Somatic mutation profile of tumor specimen TCGA-G7-6797-01A (aliquot TCGA-G7-6797-01A-11D-1961-08) from TCGA case TCGA-G7-6797, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 46.6 years (17,004 days).
Specimen TCGA-G7-6797-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ddf8518-6856-48a6-86ef-7258a369ded2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G7-6797-10A (Blood Derived Normal), aliquot TCGA-G7-6797-10A-01D-1962-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e874c39a-8835-490e-bd73-f303c52094cf

The open-access MAF lists 63 somatic variants for this specimen: 51 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Frame Shift Del 6, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP12 | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53578911; called by muse, varscan2
- ANKRD13A | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as COSV55677437; called by muse, mutect2, varscan2
- CCR2 | c.67T>A p.F23I | Missense Mutation (SNP) | VAF 125/253 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52749499; called by muse, mutect2, varscan2
- CES3 | c.1035C>A p.N345K | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as rs1296523500, COSV57594542; called by muse, mutect2, varscan2
- CHMP1A | c.83C>G p.A28G | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV53683977; called by muse, mutect2, varscan2
- CLPTM1L | c.710T>C p.L237P | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57991735; called by muse, mutect2, varscan2
- DSN1 | c.51G>T p.M17I | Missense Mutation (SNP) | VAF 88/284 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.018); catalogued as COSV65519778; called by muse, varscan2
- ETV5 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60504527; called by muse, mutect2, varscan2
- FAM71A | c.1229G>T p.R410M | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV54235024, COSV54236468; called by mutect2, varscan2
- FAT1 | c.7870G>T p.D2624Y | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71675209, COSV71676326; called by muse, mutect2, varscan2
- GATAD2A | c.1631C>T p.T544M | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs748319132, COSV53073207; called by muse, mutect2, varscan2
- GEN1 | c.1192C>T p.Q398* | Nonsense Mutation (SNP) | VAF 92/192 reads (48%) | catalogued as COSV58057741; called by muse, varscan2
- GFPT1 | c.2087T>A p.V696E (on ENST00000357308 / NM_001244710.2; = p.V678E on NM_002056.4) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61949328; called by muse, varscan2
- HEBP1 | c.364A>G p.I122V | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as COSV50009620; called by muse, varscan2
- HNF4G | c.407T>C p.I136T (on ENST00000354370 / NM_001330561.2; = p.I183T on NM_004133.5) | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as COSV62971332; called by muse, mutect2
- IREB2 | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV51924959; called by muse, mutect2, varscan2
- IREB2 | c.989T>C p.V330A | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.86); PolyPhen benign (0.024); catalogued as rs371991607; called by muse, mutect2, varscan2
- KIAA1210 | c.2099T>C p.I700T | Missense Mutation (SNP) | VAF 45/52 reads (87%) | SIFT tolerated (0.19); PolyPhen benign (0.099); catalogued as rs1299645314, COSV68178681; called by muse, mutect2, varscan2
- LRIG3 | c.2428G>T p.V810F | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV57867263; called by muse, mutect2, varscan2
- MCM10 | c.898A>C p.I300L (on ENST00000484800 / NM_182751.3; = p.I299L on NM_018518.5) | Missense Mutation (SNP) | VAF 79/170 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV66335722; called by muse, mutect2, varscan2
- NCKAP5 | c.2652G>C p.W884C | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV58461458; called by muse, mutect2, varscan2
- NF2 | c.599+1G>A p.X200_splice | Splice Site (SNP) | VAF 36/42 reads (86%) | catalogued as CS951487, COSV100099758, COSV104404753, COSV58527473; called by muse, mutect2, varscan2
- NUMA1 | c.4558C>A p.L1520M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV61188431; called by mutect2, varscan2
- NXF3 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 73/78 reads (94%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs993778263, COSV67703989; called by mutect2, varscan2
- PCBD1 | c.239A>G p.H80R | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54738613; called by muse, mutect2, varscan2
- PGAM2 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV51979086; called by muse, mutect2, varscan2
- PPFIBP1 | c.836A>C p.E279A (on ENST00000318304 / NM_177444.3; = p.E248A on NM_003622.4) | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV57295702; called by muse, mutect2, varscan2
- PPM1D | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.92); catalogued as rs200809297, COSV59956882; called by muse, mutect2, varscan2
- RIPOR1 | c.1349G>A p.R450Q (on ENST00000379312 / NM_001193522.2; = p.R446Q on NM_024519.4) | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs773792869, COSV50217719; called by muse, mutect2, varscan2
- SIX4 | c.503T>G p.I168S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV53670806; called by muse, mutect2, varscan2
- SLC26A6 | c.904-2A>G p.X302_splice | Splice Site (SNP) | VAF 8/12 reads (67%) | catalogued as COSV56573709; called by muse, mutect2, varscan2
- SLC47A2 | c.865G>C p.G289R | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV57629429; called by muse, mutect2, varscan2
- SMAD7 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.19); catalogued as rs1352334210, COSV50990945; called by muse, mutect2, varscan2
- TANC1 | c.3956T>G p.F1319C | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55092748; called by muse, mutect2, varscan2
- TASOR | c.4108C>G p.Q1370E (on ENST00000355628 / NM_001365636.2; = p.Q994E on NM_015224.3) | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs753621253, COSV58303593; called by muse, mutect2, varscan2
- TBC1D13 | c.651C>G p.I217M | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); catalogued as COSV56355087; called by muse, mutect2, varscan2
- TMED4 | c.310T>C p.S104P | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV56942263; called by muse, mutect2, varscan2
- USF3 | c.4120A>G p.M1374V | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs779440475, COSV57075401; called by muse, mutect2, varscan2
- ZBTB11 | c.3067G>A p.V1023I | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV57246117; called by muse, mutect2, varscan2
- ZMYND10 | c.1235G>A p.W412* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV51603175; called by muse, mutect2, varscan2
- ZNF207 | c.1153A>T p.N385Y | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as COSV58301100; called by muse, mutect2, varscan2
- ZNF573 | c.1252G>T p.E418* (on ENST00000536220 / NM_001172692.1; = p.E360* on NM_152360.3) | Nonsense Mutation (SNP) | VAF 112/267 reads (42%) | catalogued as COSV59826966; called by muse, mutect2, varscan2
- ZNF573 | c.1251G>T p.K417N (on ENST00000536220 / NM_001172692.1; = p.K359N on NM_152360.3) | Missense Mutation (SNP) | VAF 112/264 reads (42%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.885); catalogued as COSV59826980; called by muse, mutect2, varscan2
- BHMT | c.1110dup p.D371Rfs*21 | Frame Shift Ins (INS) | VAF 91/271 reads (34%) | called by mutect2, pindel, varscan2
- COL6A6 | c.4388del p.N1463Mfs*6 | Frame Shift Del (DEL) | VAF 144/334 reads (43%) | called by mutect2, varscan2
- CYP26B1 | c.1170dup p.S391Efs*5 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by mutect2, pindel
- GABRG3 | c.1249_1253delinsC p.F417Pfs*19 | Frame Shift Del (DEL) | VAF 29/61 reads (48%) | called by pindel, varscan2*
- KRT76 | c.340del p.S114Vfs*45 | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | called by mutect2, pindel, varscan2
- PLEKHG1 | c.2409del p.D805Ifs*5 | Frame Shift Del (DEL) | VAF 53/128 reads (41%) | called by mutect2, pindel, varscan2
- PSME4 | c.2398del p.D800Mfs*15 | Frame Shift Del (DEL) | VAF 167/460 reads (36%) | called by mutect2, pindel, varscan2
- RGS7BP | c.743del p.F248Sfs*19 | Frame Shift Del (DEL) | VAF 31/96 reads (32%) | called by mutect2, pindel, varscan2
- ACOX2 | c.591G>T p.R197= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV57150037; called by muse, varscan2
- ADAM28 | c.2199T>C p.H733= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as rs771635346, COSV56103051; called by muse, mutect2, varscan2
- DOCK11 | c.2373A>T p.A791= | Silent (SNP) | VAF 79/81 reads (98%) | catalogued as COSV52244017; called by muse, mutect2, varscan2
- FSTL1 | c.624T>C p.N208= | Silent (SNP) | VAF 61/138 reads (44%) | catalogued as COSV55235231; called by muse, mutect2, varscan2
- ITM2C | c.462G>C p.A154= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as COSV58399881; called by muse, mutect2, varscan2
- OR4C13 | c.102C>A p.I34= | Silent (SNP) | VAF 33/284 reads (12%) | catalogued as rs782572685, COSV73648842; called by muse, mutect2, varscan2
- PTK2 | c.1998G>A p.R666= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV61789216; called by muse, mutect2, varscan2
- TEDC2 | c.610C>T p.L204= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV53541509; called by muse, mutect2, varscan2
- XKR4 | c.1041C>G p.A347= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV59329187; called by muse, mutect2, varscan2
- ZSCAN20 | c.2841C>T p.I947= | Silent (SNP) | VAF 34/37 reads (92%) | catalogued as COSV63683765; called by muse, mutect2, varscan2
- FBXL21P | n.975-476del | Intron (DEL) | VAF 22/61 reads (36%) | called by mutect2, varscan2
- PRR12 | chr19:49594734 G>C | 5'Flank (SNP) | VAF 13/27 reads (48%) | catalogued as COSV55870890, COSV99882365; called by muse, mutect2, varscan2
